Gene-level copy-number profile of tumor specimen BLGSP-71-08-00217-01A from CGCI case BLGSP-71-08-00217, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: male; Vital status: Dead; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 15.0 years (5,485 days).
Specimen BLGSP-71-08-00217-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file df780304-bdea-4624-8616-458e4d294c04.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator BLGSP-71-08-00217-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,734 have no estimate.
https://portal.gdc.cancer.gov/files/f8a31fd4-06f4-4f89-a9ab-46f001fce826

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 37; copy number 1: 3,064; copy number 2: 46,822; copy number 3: 7,404; copy number 4: 1,374; copy number 5: 144; copy number 6: 2; copy number 7: 1; copy number 9: 3; copy number 14: 1; copy number 15: 37.

Homozygous deletions (total copy number 0; autosomes only): 37 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,857,161–89,245,596, 37 genes (within-gene range 0–3): IGKC, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 188 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,635,976–2,801,717, 3 genes, copy number 9 (within-gene range 2–9): TTC34, AC242022.2, AC242022.1.
- chr1:121,573,946–121,580,524, 1 gene, copy number 5: LINC01691.
- chr1:150,045,660–151,401,937, 74 genes, copy number 5 (broad region; genes not listed).
- chr1:173,500,460–176,447,919, 57 genes, copy number 5: SLC9C2, AL139142.1, AL139142.2, ANKRD45, TEX50, KLHL20, BX248409.1, RN7SKP160, CENPL, Y_RNA, DARS2, GAS5, GAS5-AS1, ZBTB37, SERPINC1, RNA5SP67, RC3H1, RNA5SP68, RC3H1-IT1, LINC02776, RPL30P1, RABGAP1L-DT, RABGAP1L, AL022400.1, GPR52, BANF1P4, NDUFAF4P4, Z99127.2, RABGAP1L-IT1, Z99127.1, RABGAP1L-AS1, RNU6-307P, Z99127.3, CACYBP, MRPS14, Y_RNA, ENTR1P2, TNN, KIAA0040, AL008626.1, RPS29P4, Z94057.1, TNR, TNR-IT1, LINC01657, LINC02803, RPS29P5, COP1, SCARNA3, AL590723.1, AL591043.2, U7, AL359265.2, RNU2-12P, AL359265.1, AL591043.1, MORF4L1P7.
- chr2:91,617,160–91,659,972, 1 gene, copy number 5 (within-gene range 2–5): LSP1P4.
- chr6:170,736,173–170,737,777, 1 gene, copy number 5: AL731684.1.
- chr9:64,810,865–64,836,341, 2 genes, copy number 5: BNIP3P4, AL359955.1.
- chr14:18,333,726–18,419,273, 4 genes, copy number 5: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr15:21,328,380–21,981,245, 37 genes, copy number 15: AC060814.4, AC060814.3, LONRF2P4, AC060814.2, CXADRP2, AC060814.1, GRAMD4P6, POTEB3, MIR3118-3, U6, NF1P9, MIR5701-2, AC183088.4, AC183088.2, AC183088.1, LINC02203, AC183088.3, AC135068.6, AC135068.2, AC135068.12, AC135068.11, AC135068.1, AC135068.4, AC135068.5, AC135068.8, AC135068.7, AC135068.9, AC135068.10, AC135068.3, AC134981.1, MIR3118-4, POTEB, RNU6-631P, ZNF519P3, NF1P2, MIR5701-3, OR11J6P.
- chr16:28,700,294–28,701,540, 1 gene, copy number 14 (within-gene range 5–58): CDC37P1.
- chr20:45,648,563–45,670,270, 1 gene, copy number 7: WFDC11.
- chr21:8,603,547–8,680,934, 2 genes, copy number 6: RPSAP68, CR381572.2.
- chr22:18,773,665–18,861,049, 4 genes, copy number 5 (within-gene range 3–6): GGT3P, AC008132.2, E2F6P1, AC008132.1.

Autosomal genes at a single copy (total copy number 1): 281. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
